Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3TB, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3TB-01A (Primary Tumor).

[page 1 of 3]
Pathology

Port

atholo

Fax:

DOB:

Physician:

Sex:

Corrected

Received

Case type: Surgical Case

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A-C) RIGHT NECK DISSECTION, LEVEL II, LEVEL III, LEVEL IV:

LEVEL II:

Two lymph nodes, no tumor present (0/2).

LEVEL III:

METASTATIC PAPILLARY CARCINOMA IN FOUR OF NINE LYMPH NODES (B).
1.3 CM IN GREATEST DIMENSION.

LEVEL IV:

METASTATIC PAPILLARY CARCINOMA IN FOUR OF NINE LYMPH NODES (4/9).
METASTATIC CARCINOMA IN SOFT TISSUE.

(D) RIGHT PARATRACHEAL NECK DISSECTION:

METASTATIC PAPILLARY CARCINOMA IN SIX OF EIGHT LYMPH NODES (6/8).

(E) LEFT SUPERIOR PARATHYROID:

Parathyroid tissue, no tumor present.

(F) TOTAL THYROID:

PAPILLARY THYROID CARCINOMA, PRIMARILY FOLLICULAR PATTERN (2.2 CM).
TUMOR EXTENDS INTO ADJACENT PARATHYROID (F6).
TUMOR PRESENT AT MARGIN.
METASTATIC PAPILLARY CARCINOMA IN ONE OF ONE LYMPH NODE (1/1).

Entire report and diagnosis completed by:

ICD-O-3
Path: carcinoma, papillary and follicular,
thyroid 8240/3
4412
R0 C95.0 carcinoma, papillary, thyroid
8260/3
Site: thyroid, NOS C73.9

GROSS DESCRIPTION

(A) CONTENTS, RIGHT LATERAL NECK DISSECTION, LEVEL II - An irregular fragment of fibroadipose tissue (8.0 x 3.0 x 0.8 cm). The specimen is serially sectioned and two lymph nodes are identified (1.5 x 0.6 x 0.4 and 2.0 x 0.8 x 0.8 cm).

SECTION CODE: A1, one lymph node bisected; A2, one lymph node.

(B) RIGHT LEFT NECK DISSECTION, LEVEL III - An irregular fragment of fibroadipose tissue, skeletal muscle (6.0 x 3.0 x 0.8 cm). The specimen is serially sectioned and nine lymph nodes are identified ranging from 0.4 x 0.3 x 0.3 to 2.0 x 0.8 x 0.5 cm.

SECTION CODE: B1, representative sections of skeletal muscle; B2, three lymph nodes; B3, four lymph nodes; B4, two lymph nodes.

(C) RIGHT CONTENTS, LEVEL IV - An irregular fragment of fibroadipose tissue (6.0 x 3.5 x 1.5 cm). The specimen is serially sectioned and 10 lymph nodes are identified ranging from 0.2 x 0.2 x 0.2 to 3.0 x 1.5 x 1.0 cm.

SECTION CODE: C1, three lymph nodes; C2, C3, one lymph node bisected; C4, C5, one lymph node bisected; C6, five lymph nodes.

(D) CONTENTS, RIGHT PARATRACHEAL NECK DISSECTION - An irregular fragment of fibroadipose tissue (5.0 x 3.0 x 1.5 cm). The specimen is serially sectioned and eight lymph nodes are identified ranging from 0.4 x 0.4 x 0.3 to 2.5 x 2.0 x 1.0 cm.

[page 2 of 3]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex:

Collected:
Received:

Pathologist:
Case type: Surgical Case

Accession:

The cut surface of the largest lymph node is [REDACTED], filled with yellow clear liquid.

SECTION CODE: D1, three lymph nodes; D2, two lymph nodes; D3, one lymph node bisected; D4, one lymph node bisected; D5, D6, one lymph node bisected.

(E) RULE OUT LEFT SUPERIOR PARATHYROID – a 0.2 x 0.2 x cm red, tan soft tissue fragment entirely submitted for frozen section as E after touch preparation.

*FS/DX: PARATHYROID TISSUE.

(F) TOTAL THYROID- Total thyroidectomy consists of right lobe (3.5 cm from lateral to medial, 2.5 cm from superior to inferior; 1.4 cm anterior to posterior), isthmus (1.4 x 0.8 x 0.3 cm) and left lobe (1.5 x 2.0 x 1.2 cm).

In the superior part of the right lobe is a firm tumor nodule which measures 2.2 x 1.4 x 1.3 cm. The cut surface of the tumor is white-tan, homogeneous, and grossly does not invade the capsule. It is 1.8 cm from the isthmus, 0.5 cm from the inferior, and within less than 0.1 cm from the superior part. Tumor and uninvolved thyroid are sampled for tumor bank.

SECTION CODE: F1-F6, tumor nodule in toto; from superior pole to inferior pole; F7, isthmus; F8-F10, left thyroid - representative sections.

CLINICAL HISTORY

Thyroid cancer.

SNOMED CODES

T-B6000, M-80503, T-C4200, M-80506

"Some tests reported here may have been developed and performance characteristics determined by
by the U.S. Food and Drug Administration."

These tests have not been specifically cleared or approved

Released by:

Page 2 of 3

Surgical Pathology Report

File under: Pathology

[page 3 of 3]
Surgical Pathology Report

Department of Pathology,

DOB:
Physician:

Sex.

Collected:

Pathologist:

Accession

Received:

Case type: Surgical Case

ADDENDUM

Addendum completed by

COMMENT

One lymph node in level II showed a psammoma body surrounded by giant cells without epithelial cells identified. A cytokeratin stain is negative for metastatic carcinoma. The above diagnosis remains unchanged.

Released by:

Page 3 of 3

Surgical Pathology Report

File under: Pathology

Source: NCI Genomic Data Commons file c1904fde-e55a-4bc4-88e2-77bbbb340f89 (TCGA-EL-A3TB.606BB6D2-537E-4C63-A696-5A8D8BB7A826.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).